CPTAC case C3N-02769 — Brain — Gliomas (CPTAC-3)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of the Clinical Proteomic Tumor Analysis Consortium (CPTAC). Disease type: Gliomas; Primary site: Brain. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/2e653fba-5d9b-446f-af7f-a986e39ed713

Demographics
Sex at birth: male; Race: asian; Year of birth: 1963; Vital status: Dead; Days to death: 1,115 days (3.1 years); Year of death: 2020; Cause of death: Cancer Related; Country of birth: China.

Diagnoses (1)
1. Glioblastoma: ICD-O-3 morphology code: 9440/3; Tissue or organ of origin: Brain, NOS; Site of resection or biopsy: Brain, NOS; Age at diagnosis: 53.9 years (19,701 days); Year of diagnosis: 2017; Last known disease status: With tumor; Days to last known disease status: 1,115 days (3.1 years); Progression or recurrence: yes; Days to recurrence: 673 days (1.8 years); Days to last follow up: 1,115 days (3.1 years).
   Pathology details: Greatest tumor dimension: 5.3 cm.
   Chemotherapy — whether it was given is not recorded by GDC; Treatment outcome: Complete Response.
   Radiation Therapy, NOS — whether it was given is not recorded by GDC; Treatment outcome: Complete Response.

Follow-up (4 entries)
- Days to follow up: 426 days (1.2 years); Disease response: Tumor Free; Karnofsky performance status: 80; ECOG performance status: 1.
- Days to follow up: 791 days (2.2 years); Disease response: Tumor Free; Karnofsky performance status: 60; ECOG performance status: 3.
- Days to follow up: 996 days (2.7 years); Disease response: With Tumor; Karnofsky performance status: 30; ECOG performance status: 4.
- Days to follow up: 1,115 days (3.1 years); Disease response: With Tumor; Progression or recurrence: Yes; Days to recurrence: 673 days (1.8 years); Karnofsky performance status: 0; ECOG performance status: 5.

Other clinical attributes
- Weight: 65 kg; Height: 170 cm; BMI: 22.49.

Exposures
- Tobacco smoking status: Lifelong Non-Smoker; Alcohol history: No; Alcohol intensity: Lifelong Non-Drinker.

Biospecimens (2 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample C3N-02769-02: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Frontal Lobe; Biospecimen laterality: Left; Preservation method: Snap Frozen; Freezing method: LN2; Days to sample procurement: -6 days; Initial weight: 150 mg; Time between excision and freezing: 15 minutes; Method of sample procurement: Tumor Resection; Diagnosis pathologically confirmed: Yes.
  Slide C3N-02769-22: Section location: Left Frontal Lobe; Percent tumor nuclei: 75; Percent necrosis: 5.
- Sample C3N-02769-71: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood Components NOS; Biospecimen anatomic site: Blood; Preservation method: Frozen; Freezing method: -20 (unit not recorded by GDC); Days to sample procurement: -6 days; Method of sample procurement: Blood Draw.
